Somatic mutation profile of tumor specimen ALCH-B3A4-TTP1-A (aliquot ALCH-B3A4-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3A4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.4 years (27,545 days).
Specimen ALCH-B3A4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19a2108c-2410-43d8-919a-a58b519daeef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3A4-NB1-A (Blood Derived Normal), aliquot ALCH-B3A4-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4702b398-a6ba-4a60-bfab-27ad805415de

The open-access MAF lists 168 somatic variants for this specimen: 110 protein-altering or splice-affecting, 36 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 36, Nonsense Mutation 12, Intron 12, Splice Site 4, RNA 4, 3'UTR 3, Splice Region 2, 5'Flank 2, 5'UTR 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.9863C>T p.S3288F | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV67985716; called by muse, mutect2, varscan2
- AL121899.2 | c.1094C>A p.S365* | Nonsense Mutation (SNP) | VAF 54/544 reads (10%) | catalogued as rs763641265, COSV67350084; called by muse, mutect2
- ANKRD30B | c.1542A>T p.K514N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV62821596; called by muse, mutect2
- ASCC3 | c.1278G>T p.L426F | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61226081; called by muse, mutect2, varscan2
- BCHE | c.1627C>G p.R543G | Missense Mutation (SNP) | VAF 47/439 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as CM990287; called by muse, mutect2, varscan2
- C11orf54 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.154); catalogued as rs772209663; called by muse, mutect2, varscan2
- C3orf33 | c.170G>T p.R57L (on ENST00000340171 / NM_001308229.2; = p.R14L on NM_173657.2) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100420070; called by muse, mutect2, varscan2
- CBX2 | c.1377C>A p.S459R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs148521974; called by muse, mutect2, varscan2
- CCKBR | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 72/607 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV58101478; called by muse, mutect2, varscan2
- CEP192 | c.2846A>G p.H949R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs748141087, COSV58063882; called by muse, mutect2, varscan2
- CGREF1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370263143; called by muse, mutect2, varscan2
- COL9A3 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs762887076; called by muse, mutect2, varscan2
- CST2 | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.093); catalogued as rs147738926; called by muse, mutect2
- CTTNBP2 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 102/817 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs760742753; called by muse, mutect2, varscan2
- CWC22 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1307605242; called by muse, mutect2, varscan2
- DSCAML1 | c.587C>T p.S196L (on ENST00000321322; = p.S136L on NM_020693.4) | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs1200800603; called by muse, mutect2
- DYNLL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs1331884113; called by muse, mutect2, varscan2
- EPHA5 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 57/648 reads (9%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as rs765840668, COSV56681725; called by muse, mutect2
- FAT2 | c.10189C>T p.R3397* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | catalogued as rs764479760; called by muse, mutect2
- GHRHR | c.883-1G>T p.X295_splice | Splice Site (SNP) | VAF 109/754 reads (14%) | catalogued as COSV58198178; called by muse, mutect2, varscan2
- GNPTAB | c.3337T>C p.F1113L | Missense Mutation (SNP) | VAF 57/500 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV54780496; called by muse, mutect2, varscan2
- IGHV4-61 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 134/1022 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.656); catalogued as rs200278942; called by muse, mutect2, varscan2
- KLHL1 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100917087; called by muse, mutect2, varscan2
- LRRC23 | c.621+7C>T | Splice Region (SNP) | VAF 89/695 reads (13%) | catalogued as rs376586732; called by muse, mutect2, varscan2
- MAGEL2 | c.2108C>G p.A703G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as rs764650142, COSV100045976; called by muse, mutect2, varscan2
- MTMR10 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV58727238; called by muse, mutect2
- MYBBP1A | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs763712203, COSV54601071; called by muse, mutect2, varscan2
- OR4D11 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 93/576 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs753702710, COSV57586000; called by muse, mutect2, varscan2
- OR51A2 | c.636T>A p.F212L | Missense Mutation (SNP) | VAF 60/507 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766879120; called by muse, mutect2, varscan2
- PCDHB7 | c.986G>C p.G329A | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.107); catalogued as rs1554280065, COSV50817541; called by muse, mutect2
- PTEN | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 13/131 reads (10%) | catalogued as rs1554897262, COSV64311473; called by muse, mutect2
- SAMHD1 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV99484116; called by muse, mutect2, varscan2
- SHOX | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); catalogued as CM074511, COSV61860608; called by muse, mutect2
- SRRM2 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV57080095; called by muse, mutect2, varscan2
- TASOR | c.1513T>C p.S505P (on ENST00000355628 / NM_001365636.2; = p.S109P on NM_015224.3) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs1418596026; called by muse, mutect2, varscan2
- TET2 | c.4633C>T p.Q1545* | Nonsense Mutation (SNP) | VAF 22/180 reads (12%) | catalogued as COSV54414599; called by muse, mutect2, varscan2
- TMC8 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs755470929; called by muse, mutect2, varscan2
- TP53BP1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55496159; called by muse, mutect2, varscan2
- USH2A | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 86/797 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as rs751720987; called by muse, mutect2
- VPS9D1 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 27/174 reads (16%) | catalogued as rs769127445, COSV66994366; called by muse, mutect2, varscan2
- WWP1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371650373; called by muse, mutect2, varscan2
- ZNF280A | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.406); catalogued as rs1183774995, COSV57482356; called by muse, mutect2, varscan2
- ABCC11 | c.2741T>A p.I914N | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRA3 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, varscan2
- ALDH1A3 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ATG10 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 69/418 reads (17%) | called by muse, mutect2, varscan2
- CATSPERD | c.784A>T p.S262C | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CCDC171 | c.3417C>A p.D1139E | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CDH8 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 87/805 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CHRD | c.107T>A p.I36N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- CNBD1 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2
- CNTN5 | c.3144T>A p.Y1048* | Nonsense Mutation (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- DDX1 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DHX40 | c.1373G>T p.R458I | Missense Mutation (SNP) | VAF 65/487 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DNAAF1 | c.1493C>A p.A498D | Missense Mutation (SNP) | VAF 81/570 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH10 | c.937G>A p.V313M (on ENST00000409039; = p.V252M on NM_207437.3) | Missense Mutation (SNP) | VAF 71/505 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DNAH5 | c.1076A>T p.Y359F | Missense Mutation (SNP) | VAF 118/1084 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ELFN1 | c.1414G>T p.G472W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPRS1 | c.389-1G>A p.X130_splice | Splice Site (SNP) | VAF 108/900 reads (12%) | called by muse, mutect2, varscan2
- FAM221B | c.743-2A>G p.X248_splice | Splice Site (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- FAT4 | c.5948T>A p.I1983N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GCC2 | c.3001G>C p.E1001Q | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPRASP1 | c.1345A>T p.T449S | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPRASP2 | c.116A>T p.K39M | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GTF3C1 | c.1930C>T p.Q644* | Nonsense Mutation (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- HCAR3 | c.1144T>A p.L382M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- HGD | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 100/862 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- HRH1 | c.1378A>T p.N460Y | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTCAP3 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAT | c.64_86del p.L22Pfs*14 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | called by mutect2, pindel
- LRP2 | c.850A>G p.K284E | Missense Mutation (SNP) | VAF 65/469 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- MAGI1 | c.1042+6G>A | Splice Region (SNP) | VAF 78/542 reads (14%) | called by muse, mutect2, varscan2
- MAP4K1 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MDGA2 | c.2000T>C p.V667A (on ENST00000399232 / NM_001113498.2; = p.V369A on NM_182830.4) | Missense Mutation (SNP) | VAF 68/562 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- MDGA2 | c.1496G>A p.S499N (on ENST00000399232 / NM_001113498.2; = p.S201N on NM_182830.4) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MKI67 | c.3412G>T p.D1138Y | Missense Mutation (SNP) | VAF 57/973 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- MTMR7 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 48/646 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2
- NLGN3 | c.1748C>T p.T583I (on ENST00000358741 / NM_181303.2; = p.T563I on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- OR13G1 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR2H2 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 29/282 reads (10%) | called by muse, mutect2
- OR52E6 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- OR5AU1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- OR6C74 | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); called by muse, mutect2
- PANK2 | c.685_699del p.E229_I233del | In Frame Del (DEL) | VAF 51/488 reads (10%) | called by mutect2, pindel
- PANX3 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLEKHA2 | c.248-1G>T p.X83_splice | Splice Site (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- POTEF | c.2156C>A p.A719D | Missense Mutation (SNP) | VAF 88/675 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- PRSS16 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- PRSS54 | c.10G>C p.A4P | Missense Mutation (SNP) | VAF 67/471 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RALGAPA2 | c.5368G>A p.V1790I | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RCAN2 | c.202A>G p.R68G | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNASE2 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 46/411 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- RORB | c.883A>T p.M295L (on ENST00000396204 / NM_001365023.1; = p.M284L on NM_006914.4) | Missense Mutation (SNP) | VAF 50/386 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ROS1 | c.6826G>C p.V2276L | Missense Mutation (SNP) | VAF 86/608 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SIGLEC9 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 18/541 reads (3%) | PolyPhen possibly damaging (0.567); called by muse, mutect2
- SLFNL1 | c.372G>C p.E124D | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.057); called by muse, mutect2
- SMURF1 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- STON2 | c.2056C>T p.Q686* (on ENST00000649389 / NM_001366849.2; = p.Q629* on NM_001256430.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/372 reads (14%) | called by muse, mutect2, varscan2
- STYXL2 | c.651C>A p.Y217* | Nonsense Mutation (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2
- SUPT20HL1 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 135/515 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SVEP1 | c.7456T>A p.W2486R | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.12254A>T p.Q4085L (on ENST00000367255 / NM_182961.4; = p.Q4014L on NM_033071.3) | Missense Mutation (SNP) | VAF 89/724 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7B | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 62/560 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by mutect2, varscan2
- TNR | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 68/502 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TRPM5 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- UBTF | c.312dup p.L105Tfs*32 | Frame Shift Ins (INS) | VAF 34/234 reads (15%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.10813C>G p.P3605A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF326 | c.1019T>C p.L340S | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF521 | c.1754A>G p.H585R | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF845 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); called by muse, varscan2
- AC013489.1 | c.804G>T p.V268= | Silent (SNP) | VAF 38/317 reads (12%) | called by muse, mutect2, varscan2
- ACSL6 | c.921G>T p.V307= (on ENST00000379240; = p.V332= on NM_001009185.3) | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as COSV99732619; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3415C>A p.R1139= | Silent (SNP) | VAF 38/314 reads (12%) | called by muse, mutect2, varscan2
- ADGRF2 | c.630C>T p.N210= (on ENST00000296862 / NM_001368115.2; = p.N142= on NM_153839.7) | Silent (SNP) | VAF 30/460 reads (7%) | called by muse, mutect2
- ASMT | c.33C>A p.L11= | Silent (SNP) | VAF 67/546 reads (12%) | called by muse, mutect2, varscan2
- BCL7C | c.594G>A p.R198= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- CSRNP2 | c.255G>T p.V85= | Silent (SNP) | VAF 60/603 reads (10%) | called by muse, mutect2
- DLG2 | c.177C>T p.V59= | Silent (SNP) | VAF 53/352 reads (15%) | catalogued as rs762066905; called by muse, mutect2, varscan2
- ELAPOR1 | c.1035C>T p.N345= | Silent (SNP) | VAF 16/354 reads (5%) | catalogued as rs1009470100, COSV64040602; called by muse, mutect2
- F10 | c.1221C>T p.Y407= | Silent (SNP) | VAF 48/347 reads (14%) | catalogued as rs759587061, COSV65023076; called by muse, mutect2, varscan2
- FAM133A | c.528C>G p.L176= | Silent (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- FAT4 | c.5214A>G p.P1738= | Silent (SNP) | VAF 61/475 reads (13%) | catalogued as COSV100629169; called by muse, mutect2, varscan2
- GRIFIN | c.294C>T p.A98= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as rs1411840829; called by muse, mutect2, varscan2
- HDAC9 | c.2952T>C p.I984= | Silent (SNP) | VAF 70/506 reads (14%) | called by muse, mutect2, varscan2
- HK1 | c.2721G>T p.V907= | Silent (SNP) | VAF 44/313 reads (14%) | called by muse, mutect2, varscan2
- HOXD10 | c.657C>T p.P219= | Silent (SNP) | VAF 54/401 reads (13%) | catalogued as rs560628362, COSV50891036; called by muse, mutect2, varscan2
- LMLN | c.939A>G p.L313= | Silent (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- MUC22 | c.4878C>T p.S1626= | Silent (SNP) | VAF 65/386 reads (17%) | called by muse, mutect2, varscan2
- NEDD9 | c.888C>T p.S296= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as rs1194473581; called by muse, mutect2
- NLRP13 | c.687G>A p.Q229= | Silent (SNP) | VAF 56/369 reads (15%) | catalogued as rs1377604216; called by muse, mutect2, varscan2
- NOS1AP | c.117C>T p.S39= | Silent (SNP) | VAF 36/373 reads (10%) | catalogued as COSV100722780; called by muse, mutect2
- NRXN3 | c.1743C>T p.Y581= (on ENST00000557594 / NM_001272020.2; = p.Y1005= on NM_004796.6) | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as rs779505235, COSV55356491; called by muse, mutect2, varscan2
- PLXND1 | c.1095G>A p.R365= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- REG3G | c.87C>A p.T29= | Silent (SNP) | VAF 26/265 reads (10%) | called by muse, mutect2
- RGS4 | c.6C>T p.C2= | Silent (SNP) | VAF 16/281 reads (6%) | catalogued as rs1448786944; called by muse, mutect2
- RPL13 | c.546C>A p.L182= | Silent (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2, varscan2
- RYR2 | c.6390G>C p.L2130= | Silent (SNP) | VAF 26/366 reads (7%) | catalogued as rs777550265, COSV100772109, COSV63712118; called by muse, mutect2
- SLITRK6 | c.1656C>G p.L552= | Silent (SNP) | VAF 35/215 reads (16%) | called by muse, mutect2, varscan2
- TGM6 | c.78C>A p.P26= | Silent (SNP) | VAF 87/461 reads (19%) | called by muse, mutect2, varscan2
- THBD | c.894C>A p.P298= | Silent (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2, varscan2
- TMA16 | c.450G>C p.L150= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- TMEM131 | c.5352G>T p.P1784= | Silent (SNP) | VAF 28/189 reads (15%) | catalogued as COSV51787824; called by muse, mutect2, varscan2
- TUBB4B | c.129G>A p.Q43= | Silent (SNP) | VAF 58/424 reads (14%) | catalogued as rs754180003; called by muse, mutect2, varscan2
- USH2A | c.10782G>T p.L3594= | Silent (SNP) | VAF 66/470 reads (14%) | called by muse, mutect2, varscan2
- YARS2 | c.1164G>A p.E388= | Silent (SNP) | VAF 51/334 reads (15%) | called by muse, mutect2, varscan2
- ZNF98 | c.495A>G p.K165= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- ADGRG6 | c.2939-30A>G | Intron (SNP) | VAF 54/606 reads (9%) | called by muse, mutect2
- ASIC4 | c.1018+33C>A | Intron (SNP) | VAF 9/28 reads (32%) | catalogued as rs750077666; called by muse, mutect2, varscan2
- C2orf83 | n.278-1291A>G | Intron (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- CCDC38 | c.38-644T>C | Intron (SNP) | VAF 48/289 reads (17%) | called by muse, mutect2, varscan2
- CLUL1 | c.*45C>G | 3'UTR (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- COLCA2 | chr11:111296301 G>T | 5'Flank (SNP) | VAF 29/344 reads (8%) | called by muse, mutect2
- DIPK2A | c.657+216A>G | Intron (SNP) | VAF 23/273 reads (8%) | called by muse, mutect2
- DLGAP1 | c.1592-14642G>A | Intron (SNP) | VAF 111/975 reads (11%) | catalogued as rs769032914; called by muse, mutect2, varscan2
- DPP6 | c.*243C>A | 3'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- ELP1 | c.3856-49T>A | Intron (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- EYS | c.1767-7250G>T | Intron (SNP) | VAF 32/256 reads (13%) | called by mutect2, varscan2
- GATD1 | c.544+34A>T | Intron (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2
- GLIS3 | c.388+47del | Intron (DEL) | VAF 14/138 reads (10%) | catalogued as rs760963734; called by mutect2, pindel, varscan2
- HTR4 | c.*1629del | 3'UTR (DEL) | VAF 51/423 reads (12%) | called by mutect2, pindel, varscan2
- JMJD7-PLA2G4B | c.1183+23C>G | Intron (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- LINC01591 | n.267G>A | RNA (SNP) | VAF 19/199 reads (10%) | catalogued as rs774873857; called by muse, mutect2, varscan2
- MIR132 | n.56A>T | RNA (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- NUGGC | c.-11C>A | 5'UTR (SNP) | VAF 35/448 reads (8%) | catalogued as rs780325957; called by muse, mutect2
- OLFM1 | chr9:135087368 G>T | 5'Flank (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- SNORD115-9 | n.26G>T | RNA (SNP) | VAF 79/787 reads (10%) | called by muse, mutect2, varscan2
- TPP1 | c.381-30G>T | Intron (SNP) | VAF 79/589 reads (13%) | called by muse, mutect2, varscan2
- UBBP4 | n.983T>C | RNA (SNP) | VAF 96/887 reads (11%) | called by muse, varscan2
